Somatic mutation profile of tumor specimen PCProject_0062_T1_WES (aliquot PCProject_0062_T1_WES_1) from CMI case PCProject_0062, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.3 years (23,125 days).
Specimen PCProject_0062_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6deefa6-748c-44ca-a919-cd78546186a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0062_SALIVA (Saliva), aliquot PCProject_0062_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2adb05c-c650-4508-9e5a-70abe2c03113

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 4, Silent 2, Frame Shift Del 2, 5'UTR 2, 3'Flank 1, Nonsense Mutation 1, In Frame Del 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELSR1 | c.5581G>A p.A1861T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.888); catalogued as rs773561584, COSV53083303; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 10/117 reads (9%) | catalogued as rs754135731; called by mutect2, varscan2*
- TNNC1 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 102/477 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as rs143020831, COSV99234638; called by muse, mutect2, varscan2
- VNN3 | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.927); catalogued as rs746389491; called by muse, mutect2, varscan2
- WDFY4 | c.3539C>T p.S1180F | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs866447241, COSV100304558; called by muse, mutect2, varscan2
- ZNF529 | c.593dup p.N198Kfs*3 | Frame Shift Ins (INS) | VAF 7/35 reads (20%) | catalogued as rs1483944944; called by mutect2, pindel
- COMP | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CUL2 | c.288G>C p.K96N | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- FAM227B | c.74G>T p.S25I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- FOXD4 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 127/730 reads (17%) | called by muse, mutect2, varscan2
- KIF14 | c.3412T>C p.W1138R | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRT6B | c.1472C>G p.S491C | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- NKX2-3 | c.451C>G p.P151A | Missense Mutation (SNP) | VAF 80/406 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NSMF | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- PITRM1 | c.761A>T p.H254L | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIOX2 | c.393_396del p.R132Qfs*36 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | called by mutect2, pindel
- RNF138 | c.430del p.T144Lfs*41 | Frame Shift Del (DEL) | VAF 23/132 reads (17%) | called by mutect2, pindel, varscan2
- ZNF107 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.714); called by mutect2, varscan2
- ELOA | c.1147C>T p.L383= | Silent (SNP) | VAF 45/238 reads (19%) | catalogued as COSV101403687; called by muse, mutect2, varscan2
- TMEM121 | c.93G>A p.E31= | Silent (SNP) | VAF 12/257 reads (5%) | called by muse, mutect2
- DPF3 | c.871+3023C>T | Intron (SNP) | VAF 84/454 reads (19%) | catalogued as rs751189350, COSV63503241; called by muse, mutect2, varscan2
- DRG1 | c.-1G>A | 5'UTR (SNP) | VAF 52/319 reads (16%) | catalogued as rs1456520595; called by muse, mutect2, varscan2
- ETV1 | c.-22G>A | 5'UTR (SNP) | VAF 27/144 reads (19%) | called by muse, mutect2, varscan2
- MAP2K5 | c.323-25A>G | Intron (SNP) | VAF 29/136 reads (21%) | catalogued as rs1203524138; called by muse, mutect2, varscan2
- MRPL20 | chr1:1399669 A>G | 3'Flank (SNP) | VAF 22/229 reads (10%) | called by muse, mutect2
- REV3L | c.9043-618T>A | Intron (SNP) | VAF 4/36 reads (11%) | catalogued as rs1356395055; called by muse, mutect2
- TNIP3 | c.946+656C>T | Intron (SNP) | VAF 12/226 reads (5%) | catalogued as rs1271767772; called by muse, mutect2
- WFDC13 | c.*13A>T | 3'UTR (SNP) | VAF 30/145 reads (21%) | called by muse, mutect2, varscan2
